Gene-level copy-number profile of tumor specimen TCGA-56-8629-01A from TCGA case TCGA-56-8629, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.9 years (23,346 days).
Specimen TCGA-56-8629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f06e5404-28ce-4258-9252-e9c0b1a99812.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8629-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e2de98e-47d2-4e89-9222-1bfb080512e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 2,151; copy number 2: 24,105; copy number 3: 14,533; copy number 4: 9,156; copy number 5: 4,443; copy number 6: 3,409; copy number 7: 928; copy number 8: 16; copy number 9: 406; copy number 10: 87; copy number 11: 3; copy number 12: 313; copy number 13: 123; copy number 14: 23; copy number 15: 10; copy number 17: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8629-01A-11D-2391-01): tumor purity 0.62, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:140,785,698–141,249,365, 52 genes: AC005609.5, PCDHA1, PCDHA2, PCDHA3, PCDHA4, PCDHA5, PCDHA6, PCDHA7, PCDHA8, PCDHA9, AC005609.2, PCDHA10, PCDHA14, AC005609.4, PCDHA11, PCDHA12, AC005609.3, AC005609.1, PCDHA13, PCDHAC1, AC010223.1, PCDHAC2, AC244517.5, PCDHB1, AC244517.9, PCDHB2, AC244517.2, PCDHB3, AC244517.1, PCDHB4, PCDHB5, AC244517.11, PCDHB6, PCDHB17P, AC244517.12, PCDHB7, PCDHB8, AC244517.8, PCDHB16, AC244517.6, AC244517.4, PCDHB9, AC244517.7, PCDHB10, PCDHB11, PCDHB12, PCDHB13, PCDHB14, AC244517.10, PCDHB18P, PCDHB19P, PCDHB15.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–26,118,408, 35 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,741 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–5,554,881, 15 genes, copy number 5: EEF1DP6, LINC01777, AL355602.1, Z98747.1, LINC01646, AJAP1, Z98886.1, BX005132.1, LINC02781, LINC02782, AL139823.1, Z98259.3, Z98259.2, Z98259.1, Z97988.2.
- chr1:5,564,071–5,564,143, 1 gene, copy number 5: Z97988.1.
- chr2:6,615,389–129,496,788, 2,218 genes, copy number 5–6 (broad region; genes not listed).
- chr2:132,406,752–134,959,342, 30 genes, copy number 5 (within-gene range 4–5): RNU6-175P, GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2, RNU6-579P, RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93, AC092623.1, MGAT5, MIR3679, RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2.
- chr2:161,992,245–201,176,687, 558 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr3:35,638,945–41,962,130, 121 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:90,202,316–198,222,513, 1,804 genes, copy number 5–14 (within-gene range 2–14) (broad region; genes not listed).
- chr4:43,133,867–63,351,472, 249 genes, copy number 6 (broad region; genes not listed).
- chr5:8,143,618–45,895,970, 550 genes, copy number 7–10 (broad region; genes not listed).
- chr6:53,381,519–74,850,484, 211 genes, copy number 6–15 (broad region; genes not listed).
- chr6:81,491,439–82,264,974, 13 genes, copy number 17: TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1, IBTK, RNU6-130P, AL121977.1.
- chr7:155,474,206–157,016,426, 22 genes, copy number 5 (within-gene range 3–5): CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1, RBM33, SHH, AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1.
- chr8:55,067,585–56,014,169, 12 genes, copy number 5 (within-gene range 2–5): AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B.
- chr8:99,527,826–99,614,081, 4 genes, copy number 5: Y_RNA, MIR599, MIR875, RN7SL350P.
- chr12:66,767–34,249,958, 850 genes, copy number 5–6 (broad region; genes not listed).
- chr12:129,013,336–129,904,025, 12 genes, copy number 5: NLRP9P1, TMEM132D, TMEM132D-AS1, AC107033.1, TMEM132D-AS2, AC079456.1, AC130404.1, AC130404.2, AC117373.1, AC117373.2, AC055717.3, AC055717.1.
- chr14:18,333,726–49,077,505, 777 genes, copy number 5 (broad region; genes not listed).
- chr14:78,059,942–95,335,757, 242 genes, copy number 5 (broad region; genes not listed).
- chr14:96,738,021–98,927,805, 24 genes, copy number 6 (within-gene range 2–6): LINC02299, AL137786.3, VRK1, LINC00618, AL049833.3, AL049833.4, AL049833.2, AL049833.1, LINC02304, AL158800.1, LINC02325, LINC02291, AL163872.1, LINC02312, AL355097.1, LINC01550, AL163932.1, LINC02295, RN7SL714P, AL132719.1, C14orf177, AL132796.1, AL132796.3, AL132796.2.
- chr18:30,290,161–34,224,952, 65 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr18:41,955,234–44,342,315, 14 genes, copy number 6 (within-gene range 4–6): PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455, AC110014.1.
- chr20:31,664,452–43,189,970, 292 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:45,137,706–54,269,542, 236 genes, copy number 5–7 (broad region; genes not listed).
- chr20:58,594,417–61,083,750, 54 genes, copy number 5: AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718.
- chr22:15,290,718–44,010,531, 1,198 genes, copy number 6–9 (broad region; genes not listed).
- chr22:44,443,327–50,801,309, 169 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,657. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
